Somatic mutation profile of tumor specimen TARGET-40-PAPKWD-01A (aliquot TARGET-40-PAPKWD-01A-01D) from TARGET case TARGET-40-PAPKWD, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 9.5 years (3,478 days).
Specimen TARGET-40-PAPKWD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a69ccff6-de78-4a4e-b20d-a44dcc21c245.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PAPKWD-10A (Blood Derived Normal), aliquot TARGET-40-PAPKWD-10A-01Y; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6c72bc97-c239-405e-8c2d-7f43b1a393b6

The open-access MAF lists 55 somatic variants for this specimen: 30 protein-altering or splice-affecting, 12 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 12, Intron 10, 3'UTR 2, Nonsense Mutation 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGO2 | c.1450C>T p.P484S | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.11); catalogued as COSV55048577; called by muse, mutect2
- ANKRD6 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774591302; called by muse, mutect2
- BRINP2 | c.557G>A p.S186N | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV64177046; called by muse, varscan2
- CPED1 | c.2668A>G p.T890A | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV60013155; called by muse, mutect2
- EYS | c.1940G>A p.C647Y | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs868696179; called by muse, varscan2
- LCN2 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.165); catalogued as COSV52982341; called by muse, mutect2
- PRR16 | c.821G>T p.S274I (on ENST00000407149 / NM_001300783.2; = p.S251I on NM_016644.2) | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1049766104; called by muse, mutect2, varscan2
- SLC25A33 | c.227A>G p.Q76R | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs1390024274; called by muse, mutect2
- SUV39H1 | c.875G>A p.R292H | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.148); catalogued as rs1557010122, COSV61920567, COSV61920913; called by muse, mutect2
- TACR3 | c.208C>G p.P70A | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV59207067; called by muse, mutect2, varscan2
- TTLL11 | c.1262C>T p.T421I | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); catalogued as rs1201397146; called by muse, mutect2, varscan2
- ABCA13 | c.15140C>T p.S5047F | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- AC005324.2 | c.697G>T p.V233L | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- ATG16L1 | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CHD9 | c.7655T>C p.V2552A (on ENST00000398510 / NM_001382353.1; = p.V2536A on NM_025134.7) | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- DSC1 | c.2327C>T p.T776I | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- GOLGA4 | c.2147A>T p.K716I | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT tolerated (0.07); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- GSG1L2 | c.188G>A p.G63D | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.332); called by muse, varscan2
- HERC2 | c.10226C>T p.A3409V | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.388); called by muse, mutect2
- ITPR2 | c.4198C>A p.L1400I | Missense Mutation (SNP) | VAF 47/84 reads (56%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- MCM7 | c.209C>A p.A70D | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- MTMR4 | c.2083C>A p.H695N | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PHF20L1 | c.2993T>A p.I998K | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.261); called by muse, mutect2
- SCN1A | c.984G>T p.E328D | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SLC52A1 | c.596_637del p.A199_R212del | In Frame Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- STON1-GTF2A1L | c.3113T>G p.L1038* | Nonsense Mutation (SNP) | VAF 45/114 reads (39%) | called by muse, mutect2, varscan2
- TASOR2 | c.3558G>C p.Q1186H | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- TENM2 | c.5507G>A p.G1836D (on ENST00000518659 / NM_001122679.2; = p.G1597D on NM_001080428.3) | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- TTN | c.91319G>C p.G30440A (on ENST00000591111; = p.G23016A on NM_003319.4) | Missense Mutation (SNP) | VAF 52/267 reads (19%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTN | c.79285G>A p.D26429N (on ENST00000591111; = p.D19005N on NM_003319.4) | Missense Mutation (SNP) | VAF 23/106 reads (22%) | PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CEMIP2 | c.1959T>C p.P653= | Silent (SNP) | VAF 15/81 reads (19%) | called by muse, mutect2
- CFAP43 | c.240G>A p.V80= | Silent (SNP) | VAF 23/71 reads (32%) | called by muse, mutect2, varscan2
- DNAH2 | c.7755G>C p.G2585= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs142996833, COSV66727720; called by muse, mutect2, varscan2
- IGHV3-23 | c.348G>A p.A116= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as rs555707296; called by muse, mutect2
- KCNH5 | c.246G>A p.R82= | Silent (SNP) | VAF 3/18 reads (17%) | called by muse, varscan2
- KIF21A | c.585G>T p.V195= | Silent (SNP) | VAF 7/57 reads (12%) | called by muse, mutect2, varscan2
- OGDH | c.1656G>A p.Q552= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as rs776853692; called by muse, mutect2, varscan2
- OR13F1 | c.913C>T p.L305= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV58252435; called by muse, mutect2
- PAX1 | c.303G>A p.E101= | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as rs1196439222; called by muse, mutect2, varscan2
- PGPEP1L | c.114C>T p.V38= | Silent (SNP) | VAF 56/1300 reads (4%) | called by muse, mutect2
- RELT | c.189C>T p.S63= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as rs1375443773; called by muse, mutect2
- SSTR4 | c.864T>A p.L288= | Silent (SNP) | VAF 20/45 reads (44%) | called by muse, mutect2, varscan2
- CFAP57 | c.2247+11G>C | Intron (SNP) | VAF 5/17 reads (29%) | catalogued as rs1380402978; called by muse, mutect2, varscan2
- CSF2RA | c.810+115C>T | Intron (SNP) | VAF 14/20 reads (70%) | catalogued as rs58223116; called by muse, varscan2
- DENND5A | c.3387+141G>C | Intron (SNP) | VAF 6/21 reads (29%) | called by muse, mutect2, varscan2
- DNM1P47 | n.4318C>A | RNA (SNP) | VAF 42/532 reads (8%) | catalogued as rs199633252; called by muse, varscan2
- HTR7 | c.*130G>T | 3'UTR (SNP) | VAF 7/14 reads (50%) | called by muse, mutect2, varscan2
- INO80C | c.379+33A>C | Intron (SNP) | VAF 8/26 reads (31%) | called by muse, mutect2
- MBP | c.750+115C>T | Intron (SNP) | VAF 5/21 reads (24%) | catalogued as rs753878418, COSV100592841; called by muse, mutect2, varscan2
- ODF2 | c.250-113G>A | Intron (SNP) | VAF 4/12 reads (33%) | catalogued as rs1266084783; called by muse, mutect2, varscan2
- SBSPON | c.*108C>T | 3'UTR (SNP) | VAF 9/28 reads (32%) | called by mutect2, varscan2
- TATDN1 | c.664+74G>C | Intron (SNP) | VAF 7/108 reads (6%) | called by muse, mutect2
- TTN | c.41382-42G>A | Intron (SNP) | VAF 7/117 reads (6%) | catalogued as rs928785610; called by muse, mutect2
- WDPCP | c.1748+105G>C | Intron (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2, varscan2
- WFDC3 | c.211+32T>G | Intron (SNP) | VAF 16/112 reads (14%) | catalogued as COSV54785274; called by muse, mutect2, varscan2
